Gene-level copy-number profile of tumor specimen TCGA-HZ-A9TJ-01A from TCGA case TCGA-HZ-A9TJ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 70.8 years (25,849 days).
Specimen TCGA-HZ-A9TJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.2984f723-a4c1-49e5-8187-99901562bab9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-A9TJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fb16c18a-70ce-4080-828a-71f171ac2556

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,644; copy number 2: 6,650; copy number 3: 24,917; copy number 4: 14,540; copy number 5: 10,295; copy number 6: 1,698; copy number 7: 24; copy number 9: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-A9TJ-01A-11D-A40V-01): tumor purity 0.53, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 75 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:20,946,906–24,162,211, 72 genes, copy number 7–9 (broad region; genes not listed).
- chr18:24,170,505–24,218,404, 3 genes, copy number 7: RNA5SP452, Metazoa_SRP, RNU6-435P.

Autosomal genes at a single copy (total copy number 1): 578. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
